TCGA case TCGA-RQ-A68N — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Brain; Tissue source site: St. Joseph's Hospital AZ. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/25ff86af-beb4-480c-b706-f3fe0306f7cf

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Primary diffuse large B-cell lymphoma of the CNS: ICD-O-3 morphology code: 9680/3; ICD-10 code: C71.7; Tissue or organ of origin: Brain stem; Site of resection or biopsy: Brain stem; Classification of tumor: primary; Age at diagnosis: 63.3 years (23,127 days); Year of diagnosis: 2012; AJCC staging edition: 7th; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 788 days (2.2 years); Sites of involvement: Lymph node, NOS / Brain, NOS.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Leucovorin + Methotrexate; Initial disease status: Initial Diagnosis; Regimen or line of therapy: High Dose Methotrexate w/Leucovorin; Days to treatment start: 8 days; Days to treatment end: 84 days; Number of cycles: 5.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Stem Cell Transplantation, NOS.

Follow-up (3 entries)
- Days to follow up: 32 days; Disease response: Tumor Free.
- Days to follow up: 788 days (2.2 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: within 2 months after completion of first-course treatment.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- CD10 (IHC): Negative.
- CD20 (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 58 kg; Height: 162 cm; BMI: 22.1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RQ-A68N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-RQ-A68N-01A-01-TSA: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 70; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
- Sample TCGA-RQ-A68N-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RQ-A68N-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Primary DLBCL of the CNS; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Treatment outcome first course: Partial Remission/Response; New tumor event diagnosis indicator: No.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal site involvement: 3; Bone marrow biopsy performed: Yes.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form, New tumor event: Pet scan after treatment results: Not Done; Treatment outcome at TCGA followup: Complete Remission/Response.
- Drug treatment: Pharmaceutical therapy drug name: High dose Methotrexate w/ Leucovorin; Stem cell transplantation: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 788 days; disease-specific survival: no event (censored), 788 days; progression-free interval: no event (censored), 788 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RQ-A68N-01A-11D-A31W-01): tumor purity 0.47, ploidy 3.92, whole-genome doublings 2.
